Somatic mutation profile of tumor specimen TCGA-DB-5277-01A (aliquot TCGA-DB-5277-01A-01D-1468-08) from TCGA case TCGA-DB-5277, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 34.8 years (12,725 days).
Specimen TCGA-DB-5277-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5631e47e-8dad-4837-8994-c854327a1b1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5277-10A (Blood Derived Normal), aliquot TCGA-DB-5277-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bc59e32-a90c-41b9-9bfb-788057c6f0bf

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Nonsense Mutation 3, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 99/109 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACLY | c.2548C>T p.Q850* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV61250383; called by muse, mutect2, varscan2
- ADAM23 | c.414C>G p.H138Q | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as rs767887528, COSV52213435; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7123C>T p.R2375* | Nonsense Mutation (SNP) | VAF 58/66 reads (88%) | catalogued as COSV51845485; called by muse, mutect2, varscan2
- CAPN11 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67237220; called by muse, mutect2, varscan2
- CDH17 | c.2320C>T p.R774W | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.332); catalogued as rs199497492, COSV50325971; called by muse, mutect2, varscan2
- ELL3 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as COSV55855634; called by muse, mutect2, varscan2
- GPR149 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV67666950; called by muse, mutect2, varscan2
- HSPG2 | c.9604G>A p.V3202M | Missense Mutation (SNP) | VAF 123/329 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760284909, COSV65933040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR1B | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759193371, COSV64051379; called by muse, mutect2, varscan2
- KIAA1841 | c.1086A>C p.I362= | Splice Region (SNP) | VAF 37/64 reads (58%) | catalogued as COSV54374460; called by muse, mutect2, varscan2
- LIPI | c.419C>G p.T140S | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60710587; called by muse, mutect2, varscan2
- LPO | c.1796G>A p.G599D | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1364611473, COSV51858351; called by muse, mutect2, varscan2
- MBD6 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs747440064, COSV63074072; called by muse, mutect2, varscan2
- MROH2B | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 42/316 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV68183170; called by muse, mutect2, varscan2
- MYH13 | c.4771A>G p.K1591E | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV52826014; called by muse, mutect2
- NBAS | c.2866G>C p.E956Q | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as COSV55719050, COSV99870824; called by muse, mutect2, varscan2
- NCOR1 | c.4070A>G p.Q1357R | Missense Mutation (SNP) | VAF 265/318 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV51971703; called by muse, mutect2, varscan2
- NUMA1 | c.4970A>G p.H1657R | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1167760864, COSV59643253; called by muse, mutect2, varscan2
- RNF139 | c.990_993del p.L330Ffs*10 | Frame Shift Del (DEL) | VAF 53/549 reads (10%) | catalogued as rs1295189379; called by mutect2, pindel
- RPAP3 | c.93G>A p.W31* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV50041620; called by muse, mutect2, varscan2
- SBSN | c.1654G>A p.G552R (on ENST00000452271 / NM_001166034.2; = p.G209R on NM_198538.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs951302654, COSV101510017, COSV71733136; called by muse, mutect2, varscan2
- SP100 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 84/154 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1435330745, COSV50974532; called by muse, mutect2, varscan2
- SPEF2 | c.2786A>G p.H929R | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV61547426; called by muse, mutect2, varscan2
- SRGAP1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61896902; called by muse, mutect2, varscan2
- TRIM51 | c.1295A>T p.Y432F | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as COSV55265890; called by muse, mutect2
- TRIM68 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56168265; called by muse, mutect2, varscan2
- TRPV5 | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1354951494, COSV54685080; called by muse, mutect2, varscan2
- ZNF343 | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs773552713, COSV53853523; called by muse, mutect2, varscan2
- CHD5 | c.2412dup p.G805Wfs*23 | Frame Shift Ins (INS) | VAF 106/321 reads (33%) | called by mutect2, pindel, varscan2
- DIP2A | c.3864T>C p.I1288= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV59476334; called by muse, mutect2, varscan2
- FBN1 | c.6354C>A p.I2118= | Silent (SNP) | VAF 36/46 reads (78%) | catalogued as CM074799, CS971734, COSV57314794; called by muse, mutect2, varscan2
- NLRP3 | c.120G>A p.P40= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs756288207, COSV60223078; called by muse, mutect2, varscan2
- PELP1 | c.1191G>C p.L397= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV52587356; called by muse, mutect2, varscan2
- TPBG | c.978G>A p.P326= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as rs748363228, COSV63882507; called by muse, mutect2, varscan2
- TTLL5 | c.2166A>G p.A722= | Silent (SNP) | VAF 139/328 reads (42%) | catalogued as rs541700043, COSV54032299; called by muse, mutect2, varscan2
- VIT | c.1362C>T p.N454= (on ENST00000389975 / NM_001177969.1; = p.N469= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs1246729509, COSV64896300; called by muse, mutect2, varscan2
- ZNF750 | c.612C>G p.G204= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV53959930; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827689 A>T | 3'Flank (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- DUSP15 | c.628+185C>T | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as rs767208850; called by muse, mutect2, varscan2
